Gene-level copy-number profile of tumor specimen BLGSP-71-17-00356-01A from CGCI case BLGSP-71-17-00356, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 24.5 years (8,932 days).
Specimen BLGSP-71-17-00356-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9da013bf-438a-4f68-8dd2-2dfd9da3e5f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-17-00356-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/085b4bad-d75e-4498-bec7-8452bc16d09c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 202; copy number 1: 3,993; copy number 2: 53,465; copy number 3: 930; copy number 4: 211; copy number 5: 11; copy number 6: 76.

Homozygous deletions (total copy number 0; autosomes only): 202 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–10,796,650, 2 genes: CASZ1, AL139423.1.
- chr2:88,885,397–88,992,931, 9 genes (within-gene range 0–1): IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8.
- chr2:89,027,171–89,027,731, 1 gene (within-gene range 0–1): IGKV3-11.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:61,642,383–61,662,690, 2 genes: Y_RNA, AL935212.1.
- chr14:21,997,539–22,552,156, 103 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,851,705–106,269,140, 80 genes (within-gene range 0–1) (broad region; genes not listed).
- chr22:50,309,030–50,327,012, 3 genes: DENND6B, CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 87 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,252,211–89,600,680, 11 genes, copy number 5: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr14:18,333,726–19,714,332, 69 genes, copy number 6 (broad region; genes not listed).
- chr21:10,640,028–13,120,807, 7 genes, copy number 6: AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 1,147. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
